Gene-level copy-number profile of tumor specimen ALCH-ABRX-TTP1-A from ALCHEMIST case ALCH-ABRX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.9 years (20,411 days).
Specimen ALCH-ABRX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 334febb1-bee0-4364-84a7-17eb0850bfdb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABRX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/350b5554-1de6-4a79-b53b-c94fc5093b4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 224; copy number 1: 7,773; copy number 2: 40,162; copy number 3: 9,312; copy number 4: 632; copy number 5: 264; copy number 6: 27; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 223 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:923,928–1,361,777, 44 genes: SAMD11, NOC2L, KLHL17, PLEKHN1, PERM1, AL645608.7, HES4, ISG15, AL645608.3, AL645608.1, AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223, C1orf159, AL390719.3, LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10, TNFRSF18, TNFRSF4, SDF4, B3GALT6, C1QTNF12, AL162741.1, UBE2J2, LINC01786, SCNN1D, ACAP3, MIR6726, PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808, MXRA8.
- chr1:2,326,201–2,326,693, 1 gene (within-gene range 0–1): AL589739.1.
- chr1:246,682,108–246,691,821, 2 genes: AL591848.2, AL591848.1.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr8:2,493,876–2,838,823, 7 genes: AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1.
- chr8:3,373,353–3,375,226, 1 gene (within-gene range 0–2): AC026991.1.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–2): RNA5SP251.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr12:116,782,105–116,782,208, 1 gene (within-gene range 0–1): RNU6-558P.
- chr12:132,489,551–132,585,188, 4 genes (within-gene range 0–2): FBRSL1, AC131212.3, AC131212.2, MIR6763.
- chr14:104,117,405–104,180,894, 4 genes: MIR203A, MIR203B, AL359399.1, KIF26A.
- chr14:105,467,793–105,492,267, 4 genes (within-gene range 0–2): AL928654.2, CRIP2, CRIP1, AL928654.3.
- chr16:525,155–584,109, 9 genes: LINC00235, CAPN15, MIR5587, MIR3176, Z97986.1, PRR35, PIGQ, NHLRC4, Z98883.1.
- chr16:629,239–800,737, 29 genes (within-gene range 0–2): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN, AL031258.1, MSLNL, MIR662, RPUSD1, CHTF18, GNG13.
- chr16:1,064,093–1,225,257, 13 genes: SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10.
- chr16:2,039,815–2,135,898, 11 genes: NTHL1, TSC2, PKD1, MIR1225, AC009065.2, AC009065.5, MIR6511B1, AC009065.6, AC009065.3, Y_RNA, MIR4516.
- chr16:88,468,918–88,469,031, 1 gene (within-gene range 0–1): MIR5189.
- chr16:88,638,572–88,977,207, 24 genes: IL17C, CYBA, MVD, SNAI3-AS1, SNAI3, RNF166, AC138028.3, CTU2, AC138028.6, PIEZO1, MIR4722, AC138028.4, AC138028.2, AC138028.5, AC138028.1, CDT1, APRT, GALNS, TRAPPC2L, PABPN1L, CBFA2T3, AC092384.2, AC092384.3, AC092384.1.
- chr17:82,018,702–82,098,294, 10 genes: CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN.
- chr18:14,695,422–14,706,597, 1 gene: GTF2IP8.
- chr20:63,558,086–63,574,239, 1 gene: HELZ2.
- chr21:7,744,962–9,018,670, 37 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3.
- chr21:44,285,838–44,443,081, 11 genes (within-gene range 0–2): AIRE, PFKL, AP001062.3, CFAP410, AP001062.1, AP001062.2, AP001063.1, TRPM2, TRPM2-AS, AP001065.2, AP001065.1.
- chr22:50,263,713–50,327,012, 5 genes: MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 293 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,262,328–132,263,042, 1 gene, copy number 6: CDC27P1.
- chr4:68,537,184–68,568,527, 1 gene, copy number 6 (within-gene range 2–6): UGT2B17.
- chr5:58,198–2,262,023, 76 genes, copy number 5–6 (broad region; genes not listed).
- chr6:26,519,351–26,519,458, 1 gene, copy number 7: RNU6-502P.
- chr7:816,615–896,435, 1 gene, copy number 7 (within-gene range 1–7): SUN1.
- chr7:51,016,212–62,275,678, 169 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:65,075,023–65,508,944, 12 genes, copy number 5 (within-gene range 5–18): AC073210.1, GTF2IP14, INTS4P1, AC104073.2, AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1, ZNF92, AC114501.3, AC114501.1.
- chr7:157,466,231–159,233,377, 25 genes, copy number 5: AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:64,091–167,043, 5 genes, copy number 5–6: AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21.
- chr8:139,600,838–139,704,109, 1 gene, copy number 5: KCNK9.
- chr15:84,422,618–84,425,882, 1 gene, copy number 5: AC243562.3.

Autosomal genes at a single copy (total copy number 1): 7,773. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
